Somatic mutation profile of tumor specimen MMRF_2126_1_BM_CD138pos (aliquot MMRF_2126_1_BM_CD138pos_T1_KHS5U_L08680) from MMRF case MMRF_2126, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 71.0 years (25,948 days).
Specimen MMRF_2126_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d217bb33-da74-43b7-b7f9-a3d1a9ff1eeb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2126_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2126_1_PB_Whole_C2_KHS5U_L08681; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dd6bda05-f8aa-4117-acbe-94382f37e920

The open-access MAF lists 132 somatic variants for this specimen: 61 protein-altering or splice-affecting, 11 silent, 60 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, 3'UTR 34, Intron 13, Silent 11, 5'UTR 7, Nonsense Mutation 5, 5'Flank 3, RNA 3, Splice Region 2, Splice Site 1, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS17 | c.1520C>A p.S507Y | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.601); catalogued as rs779332890; called by muse, mutect2, varscan2
- AGRN | c.2950G>A p.V984M | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.02); catalogued as rs371483148; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARHGAP21 | c.5362G>A p.V1788M | Missense Mutation (SNP) | VAF 55/131 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as rs566025075; called by muse, mutect2, varscan2
- CCL11 | c.205G>A p.A69T | Missense Mutation (SNP) | VAF 116/236 reads (49%) | SIFT tolerated (0.52); PolyPhen benign (0.41); catalogued as rs1429491045, COSV59925555; called by muse, mutect2, varscan2
- CFAP61 | c.2555C>T p.T852M | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.049); catalogued as COSV99842361; called by muse, mutect2
- CUBN | c.6181C>T p.P2061S | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.794); catalogued as rs755994153; called by muse, mutect2, varscan2
- IGLV3-25 | c.162C>G p.Y54* | Nonsense Mutation (SNP) | VAF 54/129 reads (42%) | catalogued as rs369844361; called by muse, mutect2, varscan2
- KCTD15 | c.514C>T p.R172C | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as rs750587104, COSV52290801; called by muse, mutect2
- LHCGR | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs1352747382, COSV54301629; called by muse, varscan2
- LRIG3 | c.3119C>T p.T1040I | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1412100626; called by muse, mutect2, varscan2
- MAZ | c.39dup p.F14Lfs*34 | Frame Shift Ins (INS) | VAF 21/54 reads (39%) | catalogued as rs767720617; called by mutect2, varscan2
- MYBPC3 | c.2449C>G p.R817G | Missense Mutation (SNP) | VAF 87/316 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM160559, COSV57022934; called by muse, mutect2, varscan2
- PCDHA3 | c.16C>T p.R6* | Nonsense Mutation (SNP) | VAF 18/64 reads (28%) | catalogued as COSV65366052; called by muse, mutect2, varscan2
- PCDHA7 | c.1919C>T p.T640M | Missense Mutation (SNP) | VAF 115/158 reads (73%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.109); catalogued as rs781952009, COSV65342627; called by muse, mutect2, varscan2
- PPRC1 | c.4376C>T p.S1459F | Missense Mutation (SNP) | VAF 100/200 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.718); catalogued as COSV53386648; called by muse, varscan2
- RARS1 | c.908A>G p.D303G | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.219); catalogued as rs1378012147; called by muse, mutect2, varscan2
- SHANK1 | c.1063G>A p.A355T | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1459706968, COSV53241893; called by muse, mutect2, varscan2
- SHOX | c.327G>C p.E109D | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs746842667; called by muse, mutect2, varscan2
- SLCO2B1 | c.705G>C p.M235I | Missense Mutation (SNP) | VAF 16/269 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as rs1454426443; called by muse, mutect2
- SPNS1 | c.1133G>A p.R378H | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.026); catalogued as rs773924844, COSV57955379; called by muse, mutect2
- TTC38 | c.1286G>A p.C429Y | Missense Mutation (SNP) | VAF 99/204 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.804); catalogued as rs538848788; called by muse, mutect2, varscan2
- UNC13D | c.2094G>A p.L698= | Splice Region (SNP) | VAF 10/132 reads (8%) | catalogued as rs1180742786; called by muse, mutect2
- UNC5D | c.1737T>G p.I579M | Missense Mutation (SNP) | VAF 45/104 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs1164767676; called by muse, mutect2, varscan2
- ZC3H6 | c.2515A>G p.I839V | Missense Mutation (SNP) | VAF 79/191 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs764308507; called by muse, mutect2, varscan2
- C1QTNF4 | c.891C>A p.Y297* | Nonsense Mutation (SNP) | VAF 57/199 reads (29%) | called by muse, mutect2, varscan2
- CD2AP | c.185A>T p.E62V | Missense Mutation (SNP) | VAF 103/229 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); called by muse, mutect2, varscan2
- CHD1 | c.51A>T p.S17= | Splice Region (SNP) | VAF 43/62 reads (69%) | called by muse, mutect2, varscan2
- CLIC5 | c.1016A>G p.E339G (on ENST00000185206 / NM_001370649.1; = p.E180G on NM_016929.5) | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.235); called by muse, mutect2
- CNTROB | c.2683A>C p.M895L | Missense Mutation (SNP) | VAF 49/125 reads (39%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- COLGALT1 | c.1048C>T p.R350W | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- CPEB1 | c.269C>T p.A90V (on ENST00000617958; = p.A30V on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/276 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.56); called by muse, mutect2, varscan2
- FAM83G | c.517C>A p.Q173K | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GABRR1 | c.1146+1G>A p.X382_splice | Splice Site (SNP) | VAF 6/102 reads (6%) | called by muse, mutect2
- GLYATL1 | c.45A>T p.K15N | Missense Mutation (SNP) | VAF 12/343 reads (3%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.717); called by muse, mutect2
- GRIK1 | c.2130G>T p.K710N | Missense Mutation (SNP) | VAF 102/150 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GTF2A1 | c.18T>G p.N6K | Missense Mutation (SNP) | VAF 167/344 reads (49%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GUCA1A | c.72G>T p.K24N | Missense Mutation (SNP) | VAF 42/82 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- IGHV2-70D | c.287A>G p.K96R | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.652); called by muse, varscan2
- IGHV2-70D | c.227A>C p.D76A | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, varscan2
- IGHV2-70D | c.217G>C p.D73H | Missense Mutation (SNP) | VAF 37/72 reads (51%) | SIFT tolerated (0.48); PolyPhen benign (0.194); called by muse, varscan2
- IGHV2-70D | c.124A>T p.T42S | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT tolerated (0.52); PolyPhen benign (0.087); called by muse, varscan2
- IGHV2-70D | c.97C>G p.P33A | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.376); called by muse, varscan2
- KPNA1 | c.259A>G p.M87V | Missense Mutation (SNP) | VAF 28/147 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- LRRC32 | c.1668G>A p.M556I | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.9); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- NCOR2 | c.2077G>T p.E693* | Nonsense Mutation (SNP) | VAF 12/144 reads (8%) | called by muse, mutect2
- OCSTAMP | c.999G>C p.W333C | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- P4HB | c.572A>T p.D191V | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.378); called by muse, mutect2
- PHLPP1 | c.33_38del p.L12_P13del | In Frame Del (DEL) | VAF 6/16 reads (38%) | called by mutect2, varscan2
- PNLIP | c.1129T>G p.F377V | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- POLR2A | c.2900G>A p.R967K | Missense Mutation (SNP) | VAF 17/152 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- PPP1R3A | c.1595A>C p.K532T | Missense Mutation (SNP) | VAF 62/145 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- PSMD11 | c.417T>A p.D139E | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, mutect2, varscan2
- RMC1 | c.17A>T p.Y6F | Missense Mutation (SNP) | VAF 41/88 reads (47%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, varscan2
- SFPQ | c.85C>T p.H29Y | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- SLC17A1 | c.1078T>C p.S360P | Missense Mutation (SNP) | VAF 46/109 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- SLCO2B1 | c.1286G>A p.G429D | Missense Mutation (SNP) | VAF 49/140 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- SVEP1 | c.3089T>A p.L1030H | Missense Mutation (SNP) | VAF 24/134 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- TDRD6 | c.3250G>T p.D1084Y | Missense Mutation (SNP) | VAF 7/111 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- WFDC9 | c.206G>T p.W69L | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, varscan2
- WFDC9 | c.97G>C p.D33H | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.281); called by muse, varscan2
- XPC | c.2776G>T p.E926* | Nonsense Mutation (SNP) | VAF 86/227 reads (38%) | called by muse, mutect2, varscan2
- BPTF | c.471T>C p.D157= | Silent (SNP) | VAF 28/52 reads (54%) | called by muse, varscan2
- CAMSAP3 | c.3528G>A p.S1176= | Silent (SNP) | VAF 42/163 reads (26%) | catalogued as rs1347908775; called by muse, mutect2, varscan2
- GPR149 | c.666G>A p.P222= | Silent (SNP) | VAF 24/143 reads (17%) | called by muse, mutect2, varscan2
- GPR87 | c.696C>T p.Y232= | Silent (SNP) | VAF 48/338 reads (14%) | catalogued as rs1205251936; called by muse, mutect2, varscan2
- IGHV2-70D | c.96A>G p.K32= | Silent (SNP) | VAF 24/54 reads (44%) | catalogued as rs1326050117; called by muse, varscan2
- LENG8 | c.2043G>A p.T681= | Silent (SNP) | VAF 48/444 reads (11%) | catalogued as rs775744959, COSV100418154; called by muse, mutect2, varscan2
- NCOR2 | c.2076G>A p.E692= | Silent (SNP) | VAF 12/144 reads (8%) | catalogued as rs370837121; called by muse, mutect2
- OBSL1 | c.897C>T p.D299= | Silent (SNP) | VAF 162/310 reads (52%) | catalogued as COSV99216931; called by muse, varscan2
- RBM33 | c.483A>G p.E161= | Silent (SNP) | VAF 8/252 reads (3%) | called by muse, mutect2
- SEMA3F | c.258C>T p.N86= | Silent (SNP) | VAF 16/374 reads (4%) | called by muse, mutect2
- TAP2 | c.1422C>T p.S474= | Silent (SNP) | VAF 19/80 reads (24%) | called by muse, mutect2, varscan2
- ABI2 | c.*2518C>T | 3'UTR (SNP) | VAF 40/78 reads (51%) | catalogued as rs192710243; called by muse, mutect2, varscan2
- ACP2 | c.114+83G>C | Intron (SNP) | VAF 90/278 reads (32%) | called by muse, mutect2, varscan2
- ACP3 | c.*1376A>G | 3'UTR (SNP) | VAF 33/257 reads (13%) | called by muse, mutect2, varscan2
- ADAMTS12 | c.*629C>A | 3'UTR (SNP) | VAF 55/183 reads (30%) | called by muse, mutect2, varscan2
- ADAMTSL1 | c.1342-485A>G | Intron (SNP) | VAF 14/57 reads (25%) | called by muse, mutect2, varscan2
- ADGRV1 | c.*25C>T | 3'UTR (SNP) | VAF 231/393 reads (59%) | called by muse, mutect2, varscan2
- AMOTL1 | c.*3826C>T | 3'UTR (SNP) | VAF 13/69 reads (19%) | called by muse, mutect2, varscan2
- ANGPTL8 | c.*101G>A | 3'UTR (SNP) | VAF 28/64 reads (44%) | called by muse, mutect2, varscan2
- ARSJ | c.*154C>T | 3'UTR (SNP) | VAF 50/102 reads (49%) | catalogued as rs974551039; called by muse, mutect2, varscan2
- BLOC1S2 | c.*779G>A | 3'UTR (SNP) | VAF 4/66 reads (6%) | called by muse, mutect2
- C14orf28 | c.*360G>A | 3'UTR (SNP) | VAF 24/55 reads (44%) | catalogued as rs576819082; called by muse, mutect2, varscan2
- CALU | c.*1347C>T | 3'UTR (SNP) | VAF 29/74 reads (39%) | called by muse, mutect2, varscan2
- CCDC33 | c.2140-313C>A | Intron (SNP) | VAF 13/327 reads (4%) | called by muse, mutect2
- CD163L1 | c.124+1818G>A | Intron (SNP) | VAF 18/42 reads (43%) | called by muse, mutect2, varscan2
- CNOT6 | c.*115T>G | 3'UTR (SNP) | VAF 12/55 reads (22%) | called by muse, varscan2
- CNOT6 | c.*174T>C | 3'UTR (SNP) | VAF 16/52 reads (31%) | called by muse, varscan2
- COL5A2 | c.*88G>T | 3'UTR (SNP) | VAF 24/44 reads (55%) | called by muse, mutect2, varscan2
- CXCL12 | c.*2710T>A | 3'UTR (SNP) | VAF 28/60 reads (47%) | catalogued as rs959532031; called by muse, mutect2, varscan2
- ECHDC1 | c.-390dup | 5'UTR (INS) | VAF 25/73 reads (34%) | called by mutect2, pindel, varscan2
- EFEMP2 | c.111+18C>T | Intron (SNP) | VAF 42/127 reads (33%) | catalogued as rs777429558; called by muse, mutect2, varscan2
- ELAVL2 | c.*477T>A | 3'UTR (SNP) | VAF 76/133 reads (57%) | called by muse, mutect2, varscan2
- FAM131A | c.*25T>C | 3'UTR (SNP) | VAF 26/82 reads (32%) | catalogued as rs760991776; called by muse, mutect2
- FKBP4 | c.515-69G>C | Intron (SNP) | VAF 12/65 reads (18%) | called by muse, mutect2, varscan2
- GALNT9 | c.1077+208G>A | Intron (SNP) | VAF 20/50 reads (40%) | catalogued as rs552474801; called by muse, mutect2, varscan2
- HEG1 | c.*1515G>A | 3'UTR (SNP) | VAF 49/147 reads (33%) | catalogued as rs1187682060; called by muse, mutect2, varscan2
- KCTD10 | c.527+141G>T | Intron (SNP) | VAF 31/49 reads (63%) | called by muse, mutect2, varscan2
- KIF16B | c.*982T>A | 3'UTR (SNP) | VAF 10/49 reads (20%) | called by muse, mutect2, varscan2
- KLHL15 | c.*1385T>G | 3'UTR (SNP) | VAF 32/32 reads (100%) | called by muse, mutect2, varscan2
- KLKP1 | n.624C>A | RNA (SNP) | VAF 11/114 reads (10%) | called by muse, mutect2
- KRT23 | c.-265G>A | 5'UTR (SNP) | VAF 40/78 reads (51%) | called by muse, mutect2, varscan2
- LHX2 | c.-344G>A | 5'UTR (SNP) | VAF 18/154 reads (12%) | called by muse, mutect2, varscan2
- LINC00632 | n.104+2616T>G | Intron (SNP) | VAF 186/188 reads (99%) | called by muse, mutect2, varscan2
- MIR873 | n.33T>C | RNA (SNP) | VAF 76/116 reads (66%) | catalogued as rs1327059722; called by muse, mutect2, varscan2
- MSL2 | c.-509del | 5'UTR (DEL) | VAF 93/329 reads (28%) | called by mutect2, pindel, varscan2
- NCL | c.1705+189T>G | Intron (SNP) | VAF 8/39 reads (21%) | called by muse, mutect2, varscan2
- NEBL-AS1 | chr10:21173851 G>A | 5'Flank (SNP) | VAF 64/142 reads (45%) | catalogued as rs758297245; called by mutect2, varscan2
- NKTR | c.*2661T>C | 3'UTR (SNP) | VAF 17/48 reads (35%) | called by muse, mutect2, varscan2
- NPC1L1 | c.*10A>G | 3'UTR (SNP) | VAF 17/139 reads (12%) | called by muse, mutect2, varscan2
- NRIP3 | c.*1866C>T | 3'UTR (SNP) | VAF 33/98 reads (34%) | called by muse, mutect2, varscan2
- OR10C1 | chr6:29439456 A>G | 5'Flank (SNP) | VAF 24/54 reads (44%) | called by muse, mutect2, varscan2
- PCDH17 | c.*3324A>G | 3'UTR (SNP) | VAF 29/65 reads (45%) | called by muse, mutect2, varscan2
- PDE3A | c.-64G>A | 5'UTR (SNP) | VAF 8/26 reads (31%) | called by muse, mutect2, varscan2
- PDZRN4 | c.*458G>A | 3'UTR (SNP) | VAF 37/72 reads (51%) | called by muse, mutect2, varscan2
- PEG10 | c.*4621A>G | 3'UTR (SNP) | VAF 8/41 reads (20%) | called by muse, mutect2, varscan2
- PHF12 | c.2089+319C>A | Intron (SNP) | VAF 9/42 reads (21%) | called by muse, mutect2, varscan2
- PIP4P1 | c.*405T>C | 3'UTR (SNP) | VAF 13/35 reads (37%) | called by muse, mutect2, varscan2
- RAB37 | c.*1688C>T | 3'UTR (SNP) | VAF 56/109 reads (51%) | called by muse, mutect2, varscan2
- RBFA | c.*3056T>A | 3'UTR (SNP) | VAF 12/29 reads (41%) | called by muse, mutect2, varscan2
- RNF166 | c.*984C>T | 3'UTR (SNP) | VAF 150/341 reads (44%) | catalogued as rs370754723; called by muse, varscan2
- RORA | c.197-60670C>T | Intron (SNP) | VAF 2/11 reads (18%) | catalogued as rs1337596924; called by muse, mutect2
- SLC25A13 | c.*147A>G | 3'UTR (SNP) | VAF 48/107 reads (45%) | catalogued as rs897852072; called by muse, mutect2, varscan2
- SLC5A12 | c.*1451G>A | 3'UTR (SNP) | VAF 11/51 reads (22%) | called by muse, mutect2, varscan2
- SP3 | c.*1475T>C | 3'UTR (SNP) | VAF 80/173 reads (46%) | called by muse, mutect2, varscan2
- SPACA9 | chr9:132878529 A>G | 5'Flank (SNP) | VAF 32/272 reads (12%) | called by muse, mutect2, varscan2
- TBL1X | c.*2450T>G | 3'UTR (SNP) | VAF 4/70 reads (6%) | called by muse, mutect2
- TLNRD1 | c.-255G>T | 5'UTR (SNP) | VAF 26/326 reads (8%) | called by muse, mutect2
- TOGARAM1 | c.-173C>T | 5'UTR (SNP) | VAF 32/111 reads (29%) | catalogued as rs1400552554; called by muse, mutect2, varscan2
- TRIM61 | c.526-2858G>T | Intron (SNP) | VAF 56/133 reads (42%) | called by muse, mutect2, varscan2
- ZDHHC14 | c.*761C>A | 3'UTR (SNP) | VAF 53/115 reads (46%) | called by muse, mutect2, varscan2
- ZNF286B | n.1818_1823del | RNA (DEL) | VAF 92/225 reads (41%) | called by mutect2, varscan2
